CCDI case PBCJEM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/55e13fc3-47ca-47a9-8bd1-c96616d0fdaa

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.9 years (5,823 days).

Biospecimens (3 samples)
- Sample 0DTP4P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTP4Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTP5C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
